Somatic mutation profile of tumor specimen TCGA-AN-A0XR-01A (aliquot TCGA-AN-A0XR-01A-11D-A10G-09) from TCGA case TCGA-AN-A0XR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 55.8 years (20,381 days).
Specimen TCGA-AN-A0XR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9ce3880-ac06-45c8-bdfa-1ba7c9dafb90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XR-10A (Blood Derived Normal), aliquot TCGA-AN-A0XR-10A-01D-A117-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/229b21bb-a0d7-4ecf-a4d5-25703e84b801

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 94/107 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62572203, COSV62573812; called by muse, mutect2, varscan2
- ASB17 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV52410105; called by muse, mutect2, varscan2
- BRWD1 | c.3668C>G p.S1223C | Missense Mutation (SNP) | VAF 169/392 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60894805; called by muse, mutect2, varscan2
- CDH9 | c.2178C>A p.D726E | Missense Mutation (SNP) | VAF 186/448 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50270765, COSV99146134; called by muse, varscan2
- GATA3 | c.1221dup p.P408Afs*99 | Frame Shift Ins (INS) | VAF 56/164 reads (34%) | catalogued as COSV100650835, COSV100651341, COSV60515158, COSV60515274, COSV60515375, COSV60517941; called by mutect2, pindel, varscan2
- GNAT2 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 130/314 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63554816; called by muse, mutect2, varscan2
- GNL3L | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 129/317 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60575817, COSV60576042; called by muse, mutect2, varscan2
- GPLD1 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs1062498, COSV57756309; called by muse, mutect2, varscan2
- HDDC2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV59532172; called by muse, mutect2, varscan2
- INTS8 | c.2874C>G p.I958M | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as COSV57375831; called by muse, mutect2, varscan2
- IQSEC3 | c.1087A>T p.S363C (on ENST00000538872 / NM_001170738.2; = p.S60C on NM_015232.1) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV58283872; called by muse, mutect2, varscan2
- JHY | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV57074570; called by muse, mutect2, varscan2
- KIF17 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV56117661; called by muse, mutect2, varscan2
- MAT2B | c.535G>T p.V179F | Missense Mutation (SNP) | VAF 140/393 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55200594; called by muse, mutect2, varscan2
- OR2Z1 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 170/382 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs782053066, COSV60692323; called by muse, mutect2, varscan2
- PCDHAC1 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV53846554; called by muse, mutect2, varscan2
- PLD5 | c.1421C>A p.A474E (on ENST00000442594; = p.A412E on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 200/649 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.366); catalogued as COSV59142362; called by muse, mutect2, varscan2
- PRMT7 | c.1730C>G p.P577R | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54711737; called by muse, mutect2, varscan2
- PTBP1 | c.1287C>G p.D429E (on ENST00000349038 / NM_031991.4; = p.D455E on NM_002819.5) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV62459524; called by muse, mutect2, varscan2
- SLC51B | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 138/338 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as rs766649904, COSV54981850; called by muse, mutect2, varscan2
- SRCAP | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 124/410 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV52671270; called by muse, mutect2, varscan2
- STXBP2 | c.1600C>T p.L534F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV55402849; called by muse, mutect2, varscan2
- USF3 | c.6155C>T p.S2052L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.35); catalogued as rs371204248; called by muse, mutect2, varscan2
- CTCF | c.780_781+6del p.X260_splice | Splice Site (DEL) | VAF 56/84 reads (67%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.476dup p.Y160Ifs*14 | Frame Shift Ins (INS) | VAF 219/380 reads (58%) | called by mutect2, pindel, varscan2
- TBX3 | c.653dup p.F219Ifs*8 (on ENST00000257566 / NM_016569.4; = p.F219Ifs*21 on NM_005996.4) | Frame Shift Ins (INS) | VAF 126/379 reads (33%) | called by mutect2, pindel, varscan2
- APC | c.7995C>G p.P2665= | Silent (SNP) | VAF 70/184 reads (38%) | catalogued as COSV57339309; called by muse, mutect2, varscan2
- CHD5 | c.1749C>T p.Y583= | Silent (SNP) | VAF 87/215 reads (40%) | catalogued as COSV52412773; called by muse, mutect2, varscan2
- CMTM2 | c.63G>A p.G21= | Silent (SNP) | VAF 41/55 reads (75%) | catalogued as COSV51748485; called by muse, mutect2, varscan2
- EEA1 | c.2778T>A p.S926= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as COSV59285033; called by muse, mutect2, varscan2
- NWD1 | c.735G>A p.P245= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs767040114, COSV60341233; called by muse, mutect2, varscan2
